Somatic mutation profile of tumor specimen TCGA-DK-A1AB-01A (aliquot TCGA-DK-A1AB-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.3 years (27,126 days).
Specimen TCGA-DK-A1AB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a79f7e77-202c-42c4-9ce1-a8bf23d45632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AB-10A (Blood Derived Normal), aliquot TCGA-DK-A1AB-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef424842-5d2b-4f59-b56b-9bfc475aa5a5

The open-access MAF lists 218 somatic variants for this specimen: 152 protein-altering or splice-affecting, 56 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 56, Nonsense Mutation 16, Intron 4, RNA 4, Splice Site 1, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, varscan2
- ABCA1 | c.6469G>C p.D2157H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV66063653; called by muse, mutect2, varscan2
- ADAM15 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV55125162; called by muse, mutect2, varscan2
- AHNAK2 | c.11594G>A p.R3865H | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs377500233, COSV60906604; called by muse, mutect2, varscan2
- AHR | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 46/172 reads (27%) | catalogued as COSV54121875; called by muse, mutect2, varscan2
- ANKRD35 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62909497; called by muse, mutect2, varscan2
- APEX2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV58188295; called by muse, mutect2, varscan2
- APOB | c.6607G>C p.D2203H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51922735; called by muse, mutect2, varscan2
- ARFIP1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142219628, COSV61884101; called by muse, mutect2, varscan2
- ARID5B | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs137983907, COSV54413919; called by muse, mutect2, varscan2
- ARMC4 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53462469, COSV53465241; called by muse, mutect2
- ATE1 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56433235; called by muse, mutect2, varscan2
- ATG2B | c.6037G>A p.E2013K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1403761670, COSV55889379; called by muse, mutect2, varscan2
- ATP8B4 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52708918; called by muse, mutect2, varscan2
- BPTF | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58831141; called by muse, mutect2, varscan2
- CAD | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53023487; called by muse, varscan2
- CATSPERB | c.2080C>G p.L694V | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56422101; called by muse, mutect2, varscan2
- CCDC113 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs151051990, COSV54685007; called by muse, mutect2, varscan2
- CCDC197 | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV58939103; called by muse, mutect2, varscan2
- CDH4 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV64641612, COSV64643972; called by muse, mutect2, varscan2
- CDYL2 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV73653824, COSV73654171; called by muse, mutect2, varscan2
- CIAO2A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV55537762; called by muse, mutect2, varscan2
- CLUAP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs756460228, COSV58892533; called by muse, mutect2, varscan2
- COG2 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64185933; called by muse, mutect2, varscan2
- COL12A1 | c.5743C>A p.P1915T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389294; called by muse, mutect2, varscan2
- COL6A3 | c.4782C>G p.F1594L | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55079430; called by muse, varscan2
- CP | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52828993; called by muse, mutect2, varscan2
- CTF1 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV99288691; called by muse, mutect2, varscan2
- CUL9 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV52725081; called by muse, mutect2, varscan2
- DMPK | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755577294, COSV52175131; called by muse, mutect2, varscan2
- DNPEP | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1242090936, COSV56110054; called by muse, mutect2, varscan2
- DPYS | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV60906279; called by muse, mutect2, varscan2
- DRC7 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as COSV61052877; called by muse, mutect2, varscan2
- DSP | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV65791006; called by muse, mutect2, varscan2
- EID2B | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58318747; called by muse, mutect2, varscan2
- EML5 | c.2214G>C p.L738F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.776); catalogued as COSV61341620; called by mutect2, varscan2
- FCHSD1 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV51836515; called by muse, mutect2, varscan2
- FGF3 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV61925204; called by muse, mutect2, varscan2
- FSHR | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as CM1314361; called by muse, mutect2, varscan2
- GABRB2 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50902880, COSV50903189; called by muse, mutect2, varscan2
- GCC2 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs866490440, COSV59173862; called by muse, mutect2, varscan2
- GTF2IRD1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV56084316; called by muse, mutect2, varscan2
- HECTD4 | c.6898G>C p.E2300Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66386550; called by muse, mutect2, varscan2
- HEG1 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.184); catalogued as COSV60759244; called by muse, mutect2, varscan2
- HERC2 | c.7048G>C p.E2350Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs1455145886, COSV55306884; called by muse, mutect2, varscan2
- IFT88 | c.178C>T p.P60S (on ENST00000319980 / NM_001318493.2; = p.P51S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.245); catalogued as COSV60671248; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as rs765436245; called by muse, mutect2
- INF2 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV53029563; called by muse, mutect2, varscan2
- INO80D | c.1300A>T p.I434L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs770510485; called by muse, mutect2
- KRTAP24-1 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV104414030, COSV61089013; called by muse, mutect2, varscan2
- LMAN2L | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53840509; called by muse, mutect2, varscan2
- LRP1 | c.10573G>C p.D3525H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54501837, COSV54513478; called by muse, mutect2, varscan2
- MANBA | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV56962752; called by muse, mutect2, varscan2
- MARCHF6 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as COSV56878664; called by muse, mutect2, varscan2
- MED24 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.15); catalogued as COSV62416921; called by muse, mutect2, varscan2
- MEGF10 | c.708G>C p.Q236H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV57244825; called by muse, varscan2
- MEGF8 | c.1964C>G p.S655* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs751800916, COSV52086214, COSV52094146; called by muse, mutect2, varscan2
- MTBP | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs1177215121, COSV59960765; called by muse, mutect2, varscan2
- MTHFR | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV56737822; called by muse, mutect2, varscan2
- MTUS1 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV50550651; called by muse, mutect2, varscan2
- MUC16 | c.26272C>G p.Q8758E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs761083443, COSV67443806; called by muse, mutect2, varscan2
- MYO1H | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs561785754, COSV60442878, COSV60444313; called by muse, mutect2, varscan2
- NAA15 | c.2565T>A p.S855R | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56717507; called by muse, mutect2, varscan2
- NDUFS1 | c.770T>G p.V257G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV51907846; called by muse, mutect2, varscan2
- NEBL | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs778833975, COSV101009172, COSV65801333; called by muse, mutect2, varscan2
- NEMF | c.2851C>T p.H951Y | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs757629295, COSV53589190, COSV53589441; called by muse, mutect2, varscan2
- NEXMIF | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV50021698, COSV50024765; called by muse, mutect2, varscan2
- NLRC5 | c.2350G>A p.V784M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs766457208, COSV52648832; called by muse, mutect2, varscan2
- NLRP9 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV60459351; called by muse, mutect2, varscan2
- NOSTRIN | c.1224G>A p.M408I (on ENST00000317647 / NM_001039724.4; = p.M330I on NM_052946.3) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58319152; called by muse, mutect2, varscan2
- NPBWR2 | c.665T>G p.V222G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV63899768; called by muse, mutect2, varscan2
- NR2F1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59067460; called by muse, mutect2, varscan2
- OR10X1 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV63766897; called by muse, mutect2
- OR2F2 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV68832497; called by muse, mutect2, varscan2
- OR2T6 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100861666, COSV63215679; called by muse, mutect2, varscan2
- OR5W2 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs12786096, COSV60614527; called by muse, mutect2, varscan2
- PAIP1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59085146; called by muse, mutect2, varscan2
- PCNX2 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753330125, COSV50781532; called by muse, mutect2, varscan2
- PDLIM7 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63080173; called by muse, mutect2, varscan2
- PHACTR4 | c.224G>C p.R75T (on ENST00000373839 / NM_001350159.2; = p.R85T on NM_023923.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65783120; called by muse, mutect2, varscan2
- PLCH1 | c.1444A>T p.T482S (on ENST00000340059 / NM_001130960.2; = p.T494S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs1412927686, COSV58186034; called by muse, mutect2, varscan2
- PLEKHG3 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55977496; called by muse, mutect2, varscan2
- PLVAP | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs757659466, COSV53083578; called by muse, mutect2, varscan2
- POLA2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV55480682; called by muse, mutect2, varscan2
- PPOX | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.11); catalogued as rs1344331354, COSV57086609; called by muse, mutect2, varscan2
- PPP1R32 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs553113019; called by muse, mutect2, varscan2
- PPP2R5D | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV55144131; called by muse, mutect2, varscan2
- PPP4R2 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV55595032; called by muse, mutect2, varscan2
- RAB3GAP1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as COSV51478596; called by muse, mutect2, varscan2
- RESF1 | c.3727G>A p.D1243N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.401); catalogued as rs999879290, COSV57019498, COSV57022320; called by muse, mutect2, varscan2
- RIPPLY2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs763323503, COSV63762351; called by muse, mutect2, varscan2
- RNPS1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57046107; called by muse, mutect2, varscan2
- RPS6KC1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs765284722, COSV65297081, COSV65301588; called by muse, mutect2, varscan2
- RSBN1L | c.2234C>G p.S745C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV58506230; called by muse, mutect2, varscan2
- RYR3 | c.8436G>C p.E2812D (on ENST00000389232; = p.E2813D on NM_001036.6) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66777279; called by muse, mutect2, varscan2
- SCYL3 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as COSV63044443; called by muse, mutect2, varscan2
- SDCBP | c.843G>C p.R281= | Splice Region (SNP) | VAF 24/98 reads (24%) | catalogued as COSV50683686; called by muse, varscan2
- SETD2 | c.5015+1G>A p.X1672_splice | Splice Site (SNP) | VAF 44/135 reads (33%) | catalogued as COSV57429774; called by muse, mutect2, varscan2
- SGO2 | c.2560G>C p.E854Q | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.413); catalogued as COSV63413783; called by muse, mutect2, varscan2
- SH3BP4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); catalogued as COSV60642182; called by muse, mutect2, varscan2
- SLC9C1 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV59884782; called by muse, mutect2, varscan2
- SLCO6A1 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); catalogued as COSV65805490, COSV65810088; called by muse, mutect2, varscan2
- SMARCA5 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV51642128; called by muse, mutect2, varscan2
- SMG6 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53962944, COSV99557830; called by muse, mutect2, varscan2
- SOX7 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58730223; called by muse, mutect2, varscan2
- SPATA17 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65119275, COSV65119631, COSV65124228; called by muse, mutect2, varscan2
- SRBD1 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55395671; called by muse, mutect2, varscan2
- SRR | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV56783897; called by muse, mutect2, varscan2
- SSC4D | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs777413330, COSV51881232; called by muse, mutect2, varscan2
- TBC1D15 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV59847324; called by muse, mutect2, varscan2
- TBC1D5 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53748932; called by muse, mutect2, varscan2
- TCF12 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51003399, COSV51030204; called by muse, mutect2, varscan2
- TGFBR3 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV53021507; called by muse, mutect2, varscan2
- TMEM79 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs374038301; called by muse, mutect2, varscan2
- TRIM32 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs758882829, COSV57749945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM59 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59086395; called by muse, mutect2, varscan2
- TRMT1L | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV62271657; called by muse, mutect2, varscan2
- TROAP | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV57743035; called by muse, mutect2, varscan2
- TSSK1B | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66814760; called by muse, mutect2, varscan2
- TTN | c.65369G>C p.R21790T (on ENST00000591111; = p.R14366T on NM_003319.4) | Missense Mutation (SNP) | VAF 50/190 reads (26%) | PolyPhen benign (0.109); catalogued as COSV59880749; called by muse, mutect2, varscan2
- TTN | c.12499G>A p.E4167K (on ENST00000591111; = p.E4121K on NM_003319.4) | Missense Mutation (SNP) | VAF 66/362 reads (18%) | catalogued as COSV59880798; called by muse, mutect2, varscan2
- TTN | c.11425G>A p.E3809K (on ENST00000591111; = p.E3763K on NM_003319.4) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | catalogued as rs867634685, COSV59880827, COSV59910034; called by muse, mutect2, varscan2
- TTYH1 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV56609570; called by muse, mutect2, varscan2
- UGGT2 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65072207; called by muse, mutect2, varscan2
- USP13 | c.171T>A p.N57K | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55862425; called by muse, mutect2, varscan2
- VIM | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56404682; called by muse, mutect2, varscan2
- VPS35L | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51976950; called by muse, mutect2, varscan2
- ZBTB45 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.391); catalogued as rs887801169, COSV54017945, COSV99564223; called by muse, mutect2, varscan2
- ZDHHC22 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV60057540; called by muse, mutect2, varscan2
- ZFHX4 | c.5083C>T p.Q1695* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV50800501; called by muse, mutect2, varscan2
- ZNF205 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs1423789518, COSV54619795; called by muse, mutect2, varscan2
- ZNF418 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 156/255 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs775386760, COSV68675463; called by muse, mutect2, varscan2
- ZNF493 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62749117, COSV62752275; called by muse, mutect2, varscan2
- ZNF57 | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV60982527; called by muse, mutect2, varscan2
- ZNF575 | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1336698602; called by muse, mutect2
- ZNF582 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV56731299, COSV56732048; called by muse, mutect2, varscan2
- ZSWIM5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV62732473; called by muse, mutect2, varscan2
- ALG13 | c.1022C>G p.S341* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2
- ARHGEF11 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARNTL2 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.6919C>T p.Q2307* (on ENST00000297405 / NM_001363185.1; = p.Q2203* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- INTS13 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- IPO8 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- KIF27 | c.3642G>C p.K1214N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MIA2 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- SDHAF3 | c.363G>C p.M121I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SPIDR | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TRAPPC6B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- TRPV1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ZNF26 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ADCY2 | c.2961C>T p.I987= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV57858537; called by muse, mutect2, varscan2
- ADGRE5 | c.1701C>T p.L567= (on ENST00000242786 / NM_078481.4; = p.L474= on NM_001784.5) | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV54390407; called by muse, mutect2, varscan2
- APBA2 | c.1407G>A p.L469= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV67104145; called by muse, mutect2, varscan2
- ATP10D | c.3990G>C p.L1330= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV56685869; called by muse, mutect2, varscan2
- ATP11A | c.3396G>C p.L1132= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV52105931; called by muse, varscan2
- BAG6 | c.399C>T p.V133= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV52987836; called by muse, mutect2, varscan2
- C20orf85 | c.126G>A p.G42= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs536022748, COSV64519009, COSV64519977; called by muse, mutect2, varscan2
- CATSPER2 | c.462G>A p.L154= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV58660170; called by muse, mutect2, varscan2
- CBLC | c.675C>G p.L225= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV54321340; called by muse, varscan2
- CDR1 | c.570C>T p.F190= | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as COSV65163831; called by muse, mutect2, varscan2
- CEACAM1 | c.687C>T p.V229= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as rs1257757740, COSV50725428; called by muse, mutect2, varscan2
- CFAP58 | c.2457C>G p.L819= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as COSV63832505; called by muse, mutect2, varscan2
- CGN | c.780C>T p.L260= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54967882, COSV54971629; called by muse, mutect2, varscan2
- CLPB | c.144G>C p.L48= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV53627245; called by muse, mutect2, varscan2
- CYFIP1 | c.730C>T p.L244= | Silent (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- DCAF6 | c.1839G>A p.Q613= (on ENST00000312263 / NM_001349778.1; = p.Q633= on NM_018442.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV56574914; called by muse, mutect2, varscan2
- DDX18 | c.1243C>T p.L415= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV54305303; called by muse, mutect2, varscan2
- DDX23 | c.1020C>T p.L340= | Silent (SNP) | VAF 114/412 reads (28%) | catalogued as COSV57281961; called by muse, mutect2, varscan2
- DGKB | c.646C>T p.L216= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- DIRAS3 | c.612C>T p.T204= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as rs748911555, COSV63970431; called by muse, mutect2, varscan2
- DNAH7 | c.11388G>A p.L3796= | Silent (SNP) | VAF 76/265 reads (29%) | catalogued as COSV56751371; called by muse, mutect2, varscan2
- DOK4 | c.528C>T p.L176= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs944234470, COSV54671689; called by muse, mutect2, varscan2
- EPHB1 | c.2175C>G p.L725= | Silent (SNP) | VAF 62/219 reads (28%) | catalogued as COSV101214961, COSV67653761; called by muse, mutect2, varscan2
- ESR2 | c.810C>T p.L270= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1481242577, COSV50828517; called by muse, mutect2, varscan2
- EXO1 | c.2322G>A p.Q774= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV62216246; called by muse, mutect2, varscan2
- FIBCD1 | c.1098C>G p.L366= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53392422; called by muse, mutect2, varscan2
- GNRHR | c.390C>T p.F130= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV56932884; called by muse, mutect2, varscan2
- H3C11 | c.222G>A p.E74= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV58898961; called by muse, mutect2, varscan2
- HTR7 | c.147G>C p.L49= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- IGLL5 | c.540G>A p.L180= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV66535054; called by muse, mutect2, varscan2
- JAKMIP1 | c.654G>C p.V218= | Silent (SNP) | VAF 37/165 reads (22%) | catalogued as COSV51521942; called by muse, mutect2, varscan2
- KLK3 | c.300C>G p.L100= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs2739452, COSV58098674; called by muse, mutect2, varscan2
- LEF1 | c.621C>T p.I207= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV54463185; called by muse, mutect2, varscan2
- LOXL3 | c.207C>T p.I69= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV51206099; called by muse, mutect2, varscan2
- LRR1 | c.378G>A p.V126= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV53562479; called by muse, mutect2, varscan2
- MASTL | c.1929G>A p.L643= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV60909380; called by muse, mutect2, varscan2
- NAV2 | c.1626G>A p.E542= (on ENST00000396087 / NM_001244963.2; = p.E519= on NM_145117.5) | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV62315016; called by muse, mutect2, varscan2
- NTSR2 | c.1119C>T p.V373= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV60990360; called by muse, mutect2, varscan2
- OR2A1 | c.483C>T p.L161= | Silent (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- OXR1 | c.2502G>A p.A834= (on ENST00000442977 / NM_001198532.1; = p.A806= on NM_018002.3) | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs186196779; called by muse, mutect2, varscan2
- PCCB | c.1116G>C p.V372= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as COSV52443401; called by muse, mutect2, varscan2
- PCDHB14 | c.1707C>T p.S569= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- PTPRG | c.3513G>A p.Q1171= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV55628270; called by muse, mutect2, varscan2
- RTCA | c.96C>T p.L32= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV53119264; called by muse, mutect2, varscan2
- RYR1 | c.9045C>G p.L3015= | Silent (SNP) | VAF 51/236 reads (22%) | catalogued as COSV62088530; called by muse, mutect2, varscan2
- SCN4A | c.4272C>T p.V1424= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV71128318; called by muse, mutect2
- SGSH | c.438C>G p.L146= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV58338380; called by muse, mutect2, varscan2
- SPTBN1 | c.4896G>A p.K1632= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV61685370; called by muse, mutect2, varscan2
- TBC1D17 | c.1236C>T p.F412= | Silent (SNP) | VAF 57/281 reads (20%) | catalogued as rs1224173602, COSV55576949; called by muse, mutect2, varscan2
- TBC1D9B | c.972C>T p.F324= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV62281030; called by muse, mutect2, varscan2
- TMEM37 | c.75C>T p.F25= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV50026783; called by muse, mutect2, varscan2
- TNXB | c.10080C>T p.V3360= (on ENST00000647633; = p.V3113= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- TPRA1 | c.480G>A p.L160= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- UNC5D | c.231G>A p.A77= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1335791003, COSV54768776; called by muse, mutect2, varscan2
- ZFHX3 | c.1221C>T p.T407= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as rs754058260, COSV51708215; called by muse, mutect2, varscan2
- ZNF485 | c.585G>A p.L195= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV62423641; called by muse, mutect2, varscan2
- CCDC32 | c.-13+21C>T | Intron (SNP) | VAF 10/49 reads (20%) | catalogued as COSV59764959; called by muse, mutect2, varscan2
- CPLANE1 | c.*3416A>T | 3'UTR (SNP) | VAF 44/151 reads (29%) | catalogued as COSV57051813; called by muse, mutect2, varscan2
- DSC1 | c.2488-104G>C | Intron (SNP) | VAF 26/102 reads (25%) | catalogued as COSV57141638; called by muse, mutect2, varscan2
- LINC01588 | n.894C>G | RNA (SNP) | VAF 43/200 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.163-58G>C | Intron (SNP) | VAF 24/118 reads (20%) | catalogued as COSV56807759; called by muse, mutect2, varscan2
- SHANK2 | c.1854-42G>A | Intron (SNP) | VAF 29/134 reads (22%) | catalogued as rs574470596, COSV53585362; called by muse, mutect2, varscan2
- SNORD114-11 | n.34C>T | RNA (SNP) | VAF 10/30 reads (33%) | catalogued as rs945187721; called by muse, mutect2, varscan2
- SNORD116-12 | n.77C>T | RNA (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by mutect2, varscan2
- TMEM99 | n.1012C>T | RNA (SNP) | VAF 45/107 reads (42%) | catalogued as rs1429583006, COSV56981556; called by muse, mutect2, varscan2
